Somatic mutation profile of tumor specimen TCGA-FY-A3R8-01A (aliquot TCGA-FY-A3R8-01A-11D-A21Z-08) from TCGA case TCGA-FY-A3R8, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 62.5 years (22,824 days).
Specimen TCGA-FY-A3R8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4281136b-21cb-411b-9711-434595fd7d83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3R8-10A (Blood Derived Normal), aliquot TCGA-FY-A3R8-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ab4233e-6a38-4809-93dd-d921c327629e

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAMTS16 | c.2231C>A p.A744D | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57009801; called by muse, mutect2, varscan2
- DCLRE1A | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63748582; called by muse, mutect2, varscan2
- FGD1 | c.1437G>T p.E479D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as COSV64309847; called by muse, mutect2, varscan2
- MRAP2 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as COSV57635454; called by muse, mutect2, varscan2
- PAQR6 | c.326C>A p.P109H (on ENST00000292291 / NM_001272108.2; = p.P3H on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as COSV52747141; called by muse, mutect2
- RYK | c.1465C>G p.L489V (on ENST00000620660 / NM_001005861.2; = p.L486V on NM_002958.4) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56064933; called by muse, mutect2, varscan2
- SLC2A5 | c.135C>G p.L45= | Splice Region (SNP) | VAF 19/37 reads (51%) | catalogued as COSV101072693, COSV66238325; called by muse, mutect2, varscan2
- ZNF488 | c.978C>G p.F326L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs181686195; called by muse, mutect2, varscan2
- PLA2G3 | c.1246_1271del p.M416Lfs*21 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | called by mutect2, pindel
- SOBP | c.544_550dup p.R184Lfs*10 | Frame Shift Ins (INS) | VAF 20/86 reads (23%) | called by mutect2, varscan2
- COL22A1 | c.3354T>C p.P1118= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV57365141; called by muse, mutect2, varscan2
- CORIN | c.2088G>T p.V696= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV56697713, COSV56701121; called by muse, mutect2, varscan2
- KRTAP24-1 | c.465T>C p.L155= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as COSV61090242; called by muse, mutect2
- LGR4 | c.1977C>T p.L659= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs1043572652, COSV60821943; called by muse, mutect2, varscan2
